Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8683, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8683-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]		
[REDACTED] Case ID	[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
In pre-pylorus, lesser curvature, there is an ulcerated tumor with 4x3x1cm in size, firm and gray surface.	Mucosa is ulcerated and necrotic. Tumor is invasion into serosa. Tumor is composed of tubules or small groups. Glands are variability in size and shape. Tumor cells are moderately stratified. Mitotic index is present. Nuclei are hyperchromatic and irregularly enlarged and prominent nucleoli. Stroma is invasion of lymphocytes.	Tubular adenocarcinoma, poorly-differentiated, infiltrating serosa

[page 3 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Antrum Tumor size: 4 x 3 x 1 cm Tumor features: Ulcerated Histologic type: Tubular adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 3/5 positive for metastasis (Adjacent lymph node 3/5) Lymphatic invasion: Present Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 7bdcc6db-a05e-4bf4-821c-27460fb982d9 (TCGA-BR-8683.E8B4CFBB-3F11-4FA9-9380-8F06A2C50CC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).